CCDI case PBCGNH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9c76a9af-c15e-4839-ba16-fc14f5442d86

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.4 years (5,626 days).

Biospecimens (3 samples)
- Sample 0DRPIX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRPJ1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DRPJ8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
